Somatic mutation profile of tumor specimen TCGA-TT-A6YO-01A (aliquot TCGA-TT-A6YO-01A-11D-A35I-08) from TCGA case TCGA-TT-A6YO, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 64.5 years (23,554 days).
Specimen TCGA-TT-A6YO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe722dce-af1e-45e7-9739-5339ab622d06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TT-A6YO-10A (Blood Derived Normal), aliquot TCGA-TT-A6YO-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d00bff90-849c-410e-b243-cf588659a6f6

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NBR1 | c.752A>G p.D251G | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs376985490; called by muse, mutect2
- ABCF1 | c.2018G>A p.G673D (on ENST00000326195 / NM_001025091.2; = p.G635D on NM_001090.3) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- AGAP3 | c.789C>A p.C263* (on ENST00000622464; = p.C299* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
